Somatic mutation profile of tumor specimen MP2PRT-PAVEUU-TBP1-A (aliquot MP2PRT-PAVEUU-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVEUU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,040 days).
Specimen MP2PRT-PAVEUU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdecc399-976b-48fa-8e03-ef1ffa18b680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEUU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEUU-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10ed066f-f1be-4ed1-b6d5-bbfc7a87a682

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 91/329 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 30/426 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANKS1B | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 138/470 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359127931, COSV61335488; called by muse, mutect2, varscan2
- ARHGAP39 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 63/825 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52773546; called by muse, mutect2
- NCAM2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 79/513 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370033455; called by muse, mutect2, varscan2
- NT5C3B | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 166/638 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539074806; called by muse, mutect2, varscan2
- PNPLA7 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 164/410 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs145027368; called by muse, mutect2, varscan2
- POLR2A | c.1267A>T p.N423Y | Missense Mutation (SNP) | VAF 191/667 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100495793; called by muse, mutect2, varscan2
- TOPAZ1 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 163/398 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs939894576; called by muse, mutect2, varscan2
- BANP | c.736C>T p.R246C (on ENST00000286122; = p.R215C on NM_017869.4) | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTCF | c.1674_1675insCC p.K559Pfs*26 | Frame Shift Ins (INS) | VAF 147/464 reads (32%) | called by mutect2, pindel, varscan2
- GRIA2 | c.2614G>T p.G872C | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3OR15-7 | c.234G>A p.T78= | Silent (SNP) | VAF 141/361 reads (39%) | called by muse, mutect2, varscan2
- MAP2 | c.4152C>T p.D1384= | Silent (SNP) | VAF 97/262 reads (37%) | catalogued as rs571107524, COSV52288764; called by muse, mutect2, varscan2
- UNC13A | c.4032G>A p.A1344= | Silent (SNP) | VAF 166/424 reads (39%) | catalogued as rs552048814; called by muse, mutect2, varscan2
- URB1 | c.6261C>T p.S2087= | Silent (SNP) | VAF 205/736 reads (28%) | catalogued as rs1180035393, COSV57937147; called by muse, mutect2, varscan2
